Gene-level copy-number profile of tumor specimen RC-B659-TBP1-A from RC case RC-B659, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 44.2 years (16,159 days).
Specimen RC-B659-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f234e733-c747-48d7-9a4b-1ad8e7c080c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B659-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/072f3180-3107-44af-a95e-2a3d31e1cfdd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 184; copy number 1: 6; copy number 2: 41,752; copy number 3: 16,459.

Homozygous deletions (total copy number 0; autosomes only): 184 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,732,636, 3 genes (within-gene range 0–3): PPIAP70, AC104164.1, PPIAP71.
- chr9:16,203,935–17,503,923, 12 genes: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:17,906,563–18,910,950, 1 gene (within-gene range 0–2): ADAMTSL1.
- chr9:18,573,306–18,718,526, 3 genes (within-gene range 0–2): MIR3152, RN7SKP258, RAP1BP1.
- chr9:21,638,285–28,670,286, 69 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:22,086,407–22,552,156, 96 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
